Gene-level copy-number profile of tumor specimen C3L-02545-03 from CPTAC case C3L-02545, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G1; Age at diagnosis: 55.9 years (20,431 days).
Specimen C3L-02545-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c322409a-b48c-469a-a405-b0594d7fc4e7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02545-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/bcbca14a-1789-40c1-a082-9838024ab49e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 506; copy number 2: 51,923; copy number 3: 3,450; copy number 4: 2,518; copy number 5: 7.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,505,430–161,605,099, 6 genes, copy number 5 (within-gene range 4–5): FCGR2A, AL590385.2, HSPA6, RPS23P10, FCGR3A, AL590385.1.
- chr12:31,105,105–31,106,830, 1 gene, copy number 5: AC008013.3.

Autosomal genes at a single copy (total copy number 1): 506. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
